Gene-level copy-number profile of tumor specimen HCM-BROD-0579-C16-06A from HCMI case HCM-BROD-0579-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 36.9 years (13,485 days).
Specimen HCM-BROD-0579-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67ebb8ee-54d2-4ca6-9a83-b8fe013859ab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0579-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/e9928179-7166-4640-b00b-0e21823fd9b7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 136; copy number 2: 3,730; copy number 3: 23,152; copy number 4: 14,351; copy number 5: 9,687; copy number 6: 6,279; copy number 7: 351; copy number 8: 107; copy number 9: 70; copy number 10: 104; copy number 11: 34; copy number 12: 3; copy number 13: 54; copy number 14: 17; copy number 15: 3; copy number 16: 28; copy number 17: 43; copy number 18: 22; copy number 19: 12; copy number 20: 136; copy number 23: 10; copy number 26: 46.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–91,112,790, 2 genes (within-gene range 0–3): TMSB4XP8, AC004054.1.
- chr8:7,190,901–7,200,857, 2 genes: RPS3AP33, AF228730.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,040 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:17,816,460–20,352,234, 32 genes, copy number 10–19: MSGN1, KCNS3, AC079802.1, AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P, AC106053.1, LINC01376, MIR4757, OSR1, AC010096.1, LINC01808, AC019055.1, CISD1P1, LINC00954, TTC32, AC013400.1, WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2.
- chr2:20,999,313–23,708,611, 28 genes, copy number 7: AC115619.1, APOB, AC010872.1, TDRD15, AC067959.1, AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822, RN7SL117P, AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830, LINC01884, RN7SKP27, AC018467.1, AC012506.1, AC012506.3, AC012506.2, AC012506.4, KLHL29, AC011239.1, AC011239.2, AC009242.1.
- chr2:24,491,914–24,770,702, 1 gene, copy number 10 (within-gene range 5–10): NCOA1.
- chr2:24,676,309–27,159,229, 71 genes, copy number 10 (broad region; genes not listed).
- chr2:53,864,069–58,252,525, 60 genes, copy number 7: PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63, EIF2S2P7, AC068276.1, AC073875.1, ACTG1P22, VRK2, AC068193.1, FANCL, AC007250.1, EIF3FP3.
- chr2:58,427,799–59,063,766, 1 gene, copy number 7 (within-gene range 5–7): LINC01122.
- chr2:59,014,354–59,279,400, 2 genes, copy number 7 (within-gene range 6–7): AC007092.1, LINC01793.
- chr2:59,238,703–59,733,396, 3 genes, copy number 7 (within-gene range 6–7): AC007179.2, AC007179.1, AC007179.3.
- chr7:83,955,777–99,679,998, 232 genes, copy number 7–26 (broad region; genes not listed).
- chr7:101,815,904–105,522,271, 86 genes, copy number 9–11 (broad region; genes not listed).
- chr12:21,437,615–21,775,600, 11 genes, copy number 20: PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8.
- chr12:21,827,210–21,887,957, 2 genes, copy number 20 (within-gene range 3–20): AC008250.1, AC008250.2.
- chr12:25,004,342–25,250,936, 9 genes, copy number 18 (within-gene range 3–18): IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:29,500,840–29,784,759, 1 gene, copy number 19 (within-gene range 4–19): TMTC1.
- chr12:29,658,376–29,658,798, 1 gene, copy number 19: RPL21P99.
- chr12:37,575,587–48,765,790, 205 genes, copy number 8–13 (broad region; genes not listed).
- chr12:56,271,699–56,488,414, 19 genes, copy number 17: CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2.
- chr12:73,648,666–73,846,188, 4 genes, copy number 16: AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:73,906,940–74,049,981, 2 genes, copy number 16: AC136188.1, LINC02394.
- chr12:79,690,144–80,029,631, 8 genes, copy number 19 (within-gene range 3–19): AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38.
- chr12:112,907,628–113,098,028, 6 genes, copy number 14 (within-gene range 3–14): AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1.
- chr16:32,103,245–49,275,579, 256 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 136. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
